TCGA case TCGA-FS-A4F0 — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Essen. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4eb16fb1-0fcf-4c47-80fa-b7acc3a59a12

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 67 years; Vital status: Alive.

Diagnoses (8)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C49.9; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Connective, subcutaneous and other soft tissues, NOS; Classification of tumor: Progression; Age at diagnosis: 69.7 years (25,446 days); Days to diagnosis: 729 days (2.0 years); Prior treatment: Yes; Days to last follow up: 2,367 days (6.5 years).
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Interferon; Timepoint category: Prior to Procurement.
   Recorded as not given: Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 67.7 years (24,717 days); Year of diagnosis: 2003; AJCC staging edition: 6th; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Recombinant Interferon Alfa; Days to treatment start: 82 days; Days to treatment end: 568 days (1.6 years); Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Dacarbazine; Days to treatment start: 1,359 days (3.7 years); Days to treatment end: 1,521 days (4.2 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine + Treosulfan; Days to treatment start: 1,543 days (4.2 years); Days to treatment end: 1,603 days (4.4 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
3. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: V; Sites of involvement: Skin, Trunk; Ulceration indicator: No.
   Pathology details: Breslow thickness category: >4.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
4. Recurrence of diagnosis 2 (Malignant melanoma, NOS). Age at diagnosis: 70.1 years (25,589 days); Days to diagnosis: 872 days (2.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 858 days (2.3 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
5. Recurrence of diagnosis 2 (Malignant melanoma, NOS). Age at diagnosis: 70.6 years (25,772 days); Days to diagnosis: 1,055 days (2.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,055 days (2.9 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.
6. Recurrence of diagnosis 2 (Malignant melanoma, NOS). Age at diagnosis: 71.3 years (26,045 days); Days to diagnosis: 1,328 days (3.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,328 days (3.6 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.
7. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Lung, NOS. Age at diagnosis: 71.4 years (26,076 days); Days to diagnosis: 1,359 days (3.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
8. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Lymph node, NOS. Age at diagnosis: 72.7 years (26,545 days); Days to diagnosis: 1,828 days (5.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,828 days (5.0 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.

Follow-up (6 entries)
- Day 872 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 872 days (2.4 years).
- Day 1,055 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,055 days (2.9 years).
- Day 1,328 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,328 days (3.6 years).
- Day 1,359 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 1,359 days (3.7 years).
- Day 1,828 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 1,828 days (5.0 years).
- Days to follow up: 2,367 days (6.5 years); Disease response: Tumor Free.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FS-A4F0-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Initial weight: 20 mg.
  Slide TCGA-FS-A4F0-06A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FS-A4F0-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: Yes; Tumor status: Tumor free; Breslow thickness at diagnosis: 14; Primary melanoma tumor ulceration: No; Radiation therapy to primary: No; Primary location: Regional Cutaneous or Subcutaneous Tissue (includes satellite and in-transit metastasis); Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: Yes; Ifn treatment 90 days prior to resection: Yes.
- Sites of primary melanomas: Primary multiple at diagnosis: No; Primary at diagnosis count: 1.
- Sites of primary melanomas, Site: Submitted tumor site: Trunk.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Subsequent known primaries: No.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Drug treatment 2: Pharmaceutical therapy drug name: Interferon alpha.
- Drug treatment 3: Pharmaceutical therapy drug name: Dtic; Treatment best response: Clinical Progressive Disease.

GDC annotations on this case (curator notes; quoted as recorded):
- Acceptable treatment for TCGA tumor: Patient received interferon for the specimen submitted to TCGA.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,367 days; disease-specific survival: no event (censored), 2,367 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 872 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FS-A4F0-06A-11D-A24Q-01): tumor purity 0.98, ploidy 1.92, whole-genome doublings 0.
